Somatic mutation profile of tumor specimen 0DJKL0 from CCDI case PBBWUS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,812 days).
Specimen 0DJKL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12a4077-6e2b-4ed9-9b0b-71309f8ffae7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJKK8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a139bd0e-b9b1-4a93-8643-4e0a845db5f6

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 3'UTR 2, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 6531/6842 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 172/605 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDIT4L | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 238/887 reads (27%) | catalogued as rs1426364700, COSV56767243; called by muse, mutect2, varscan2
- PTPN6 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as rs782079530, COSV59684395; called by muse, mutect2
- TP53 | c.715A>T p.N239Y | Missense Mutation (SNP) | VAF 190/560 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52664075, COSV52685174, COSV52979974, COSV53345856; called by muse, mutect2
- CENPC | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 56/1328 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2
- EPG5 | c.5950C>A p.Q1984K | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.229); called by muse, mutect2
- KIF4B | c.2426T>G p.V809G | Missense Mutation (SNP) | VAF 42/1078 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- NBEAL2 | c.1177A>G p.S393G | Missense Mutation (SNP) | VAF 380/638 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- NEDD4L | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 80/1270 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- PRSS37 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 134/1920 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPE65 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 54/1352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 28/1209 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- EZHIP | c.249C>T p.A83= | Silent (SNP) | VAF 363/452 reads (80%) | called by muse, mutect2, varscan2
- HPS1 | c.567G>A p.R189= | Silent (SNP) | VAF 62/790 reads (8%) | called by muse, mutect2
- PIK3CG | c.849C>T p.G283= | Silent (SNP) | VAF 655/1075 reads (61%) | catalogued as rs766973241, COSV63252242; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 54/1754 reads (3%) | called by muse, mutect2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 28/1188 reads (2%) | catalogued as rs1267156464; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- MEF2B | c.*13C>T | 3'UTR (SNP) | VAF 78/177 reads (44%) | catalogued as rs1026191107; called by muse, mutect2, varscan2
- PDCL2 | c.-52G>A | 5'UTR (SNP) | VAF 33/707 reads (5%) | catalogued as COSV51698724; called by muse, mutect2
- SKI | c.*29G>A | 3'UTR (SNP) | VAF 23/454 reads (5%) | called by muse, mutect2
